Somatic mutation profile of tumor specimen HCM-BROD-1078-C49-06B (aliquot HCM-BROD-1078-C49-06B-11D-A881-36) from HCMI case HCM-BROD-1078-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 45.9 years (16,769 days).
Specimen HCM-BROD-1078-C49-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25b914bf-e7a5-4d34-a118-d3e9134b289c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1078-C49-10A (Blood Derived Normal), aliquot HCM-BROD-1078-C49-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3777b35b-5086-4dd9-ac55-cae560dc6687

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER3 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 285/579 reads (49%) | catalogued as rs764804784, COSV58471342; called by muse, mutect2, varscan2
- ASPM | c.3424C>T p.R1142C | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775031676; called by muse, mutect2, varscan2
- B4GALT7 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 208/464 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs1331979413; called by muse, mutect2, varscan2
- EYA4 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 227/383 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs552148856; called by muse, mutect2, varscan2
- FHOD3 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 15/429 reads (3%) | catalogued as COSV99942568; called by muse, mutect2
- KCNB1 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 234/524 reads (45%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.003); catalogued as rs142461221; called by muse, mutect2, varscan2
- MYB | c.41A>G p.E14G | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs753940197; called by muse, mutect2, varscan2
- NUP58 | c.1167G>A p.M389I | Missense Mutation (SNP) | VAF 104/111 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1460892451; called by muse, mutect2, varscan2
- P2RY8 | c.665del p.R222Pfs*41 | Frame Shift Del (DEL) | VAF 434/1068 reads (41%) | catalogued as COSV67177238; called by mutect2, pindel, varscan2
- PRPF4B | c.961A>G p.K321E | Missense Mutation (SNP) | VAF 202/429 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs1460994628, COSV100527977; called by muse, mutect2, varscan2
- PVALB | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 156/345 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137928260, COSV53413338; called by muse, mutect2, varscan2
- SORCS3 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 103/118 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs774027756, COSV63798536; called by muse, mutect2, varscan2
- TNXB | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 66/650 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100926584; called by muse, mutect2
- YIPF7 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 156/345 reads (45%) | catalogued as COSV60656432; called by muse, mutect2, varscan2
- AOX1 | c.3602T>A p.I1201K | Missense Mutation (SNP) | VAF 132/305 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CASR | c.2933T>C p.V978A (on ENST00000490131; = p.V1055A on NM_000388.4) | Missense Mutation (SNP) | VAF 174/403 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DISP3 | c.1859T>A p.L620Q | Missense Mutation (SNP) | VAF 170/384 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- FERMT3 | c.554T>C p.F185S | Missense Mutation (SNP) | VAF 232/552 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FIGNL2 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 294/624 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- NECTIN4 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 227/491 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTOV1 | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 229/254 reads (90%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PTPRK | c.1514del p.N505Ifs*5 | Frame Shift Del (DEL) | VAF 285/561 reads (51%) | called by mutect2, pindel, varscan2
- SAMD7 | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYC1 | c.232C>T p.L78= | Silent (SNP) | VAF 309/640 reads (48%) | catalogued as COSV100010471; called by muse, mutect2, varscan2
- DIS3L | c.228T>G p.P76= | Silent (SNP) | VAF 153/318 reads (48%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1158C>T p.S386= | Silent (SNP) | VAF 47/879 reads (5%) | catalogued as COSV101422498; called by muse, mutect2
- FMNL3 | c.1614C>T p.P538= | Silent (SNP) | VAF 153/327 reads (47%) | called by muse, mutect2, varscan2
- ITPKB | c.2559C>G p.A853= | Silent (SNP) | VAF 135/324 reads (42%) | catalogued as COSV99684301; called by muse, mutect2, varscan2
- RNF207 | c.1845T>C p.H615= | Silent (SNP) | VAF 220/231 reads (95%) | catalogued as rs757210141; called by muse, mutect2
- RPL6 | c.594A>G p.S198= | Silent (SNP) | VAF 175/386 reads (45%) | called by muse, mutect2, varscan2
- TJP1 | c.993G>A p.Q331= | Silent (SNP) | VAF 173/364 reads (48%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-7520C>T | Intron (SNP) | VAF 176/421 reads (42%) | catalogued as rs587725057, COSV57686973; called by muse, varscan2
